Somatic mutation profile of tumor specimen 0DM4XM from CCDI case PBCADP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,464 days).
Specimen 0DM4XM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d43e9987-fa59-4b67-b217-cd12401443d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0b7229-3a08-40a0-b52b-62b7eba15163

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, Silent 3, 5'UTR 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7508T>G p.V2503G | Missense Mutation (SNP) | VAF 214/1153 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.108); catalogued as COSV71288866; called by muse, mutect2, varscan2
- KBTBD4 | c.888_889insGGG p.R296_R297insG | In Frame Ins (INS) | VAF 240/429 reads (56%) | catalogued as COSV58597484; called by mutect2, varscan2
- KRT25 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 230/1775 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs754517768, COSV100380021, COSV56444403; called by muse, mutect2, varscan2
- TP63 | c.1131G>A p.P377= | Splice Region (SNP) | VAF 231/756 reads (31%) | catalogued as rs775491637, COSV53204469; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 42/1287 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- NAT2 | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 19/581 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- NUP188 | c.1430T>A p.L477H | Missense Mutation (SNP) | VAF 53/1074 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- PRKCD | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 25/940 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2
- SFTPD | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 21/694 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZG16B | c.223A>C p.T75P | Missense Mutation (SNP) | VAF 141/679 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MUC16 | c.43161C>T p.T14387= | Silent (SNP) | VAF 175/869 reads (20%) | catalogued as rs149588972; called by muse, mutect2, varscan2
- TESMIN | c.216C>T p.G72= | Silent (SNP) | VAF 359/795 reads (45%) | called by muse, mutect2, varscan2
- VIT | c.1527C>A p.G509= (on ENST00000389975 / NM_001177969.1; = p.G524= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/1201 reads (3%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 18/502 reads (4%) | called by muse, mutect2
- KIF9 | c.1060-21C>T | Intron (SNP) | VAF 41/580 reads (7%) | called by muse, mutect2
- LRAT | c.-1-21A>T | Intron (SNP) | VAF 70/257 reads (27%) | called by muse, mutect2, varscan2
- PDXDC1 | c.1293+53C>T | Intron (SNP) | VAF 136/1170 reads (12%) | catalogued as rs761213194, COSV100363565; called by muse, mutect2, varscan2
- PRR23B | c.-56C>T | 5'UTR (SNP) | VAF 14/271 reads (5%) | catalogued as rs1366287590, COSV100271853; called by muse, mutect2
